Gene-level copy-number profile of tumor specimen TCGA-06-5411-01A from TCGA case TCGA-06-5411, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.6 years (18,832 days).
Specimen TCGA-06-5411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.808d2195-34fb-4e65-ae63-3a6b3e65a088.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-5411-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6292ff3f-4656-4c2e-976f-969f9cbbfd6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 8,375; copy number 2: 48,337; copy number 3: 2,977; copy number 4: 37; copy number 26: 50; copy number 28: 38; copy number 31: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-5411-01A-01D-1694-01): tumor purity 0.64, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,960,745–51,060,103, 3 genes: CDKN2C, MIR4421, MIR6500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 91 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,893,698–158,294,774, 41 genes, copy number 28–31: PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52, AL357143.1, AL357143.2, AL138900.1, LINC02772, AL138900.2, AL732406.1, AL353899.1, FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C.
- chr1:203,318,996–205,022,822, 50 genes, copy number 26 (within-gene range 2–26): RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1.

Autosomal genes at a single copy (total copy number 1): 5,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
